Somatic mutation profile of tumor specimen TCGA-ZB-A96V-01A (aliquot TCGA-ZB-A96V-01A-11D-A428-09) from TCGA case TCGA-ZB-A96V, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 44.5 years (16,245 days).
Specimen TCGA-ZB-A96V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0f7d455-75c9-4fd5-86ab-ce695c44a5de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96V-10A (Blood Derived Normal), aliquot TCGA-ZB-A96V-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a725cff-8dd9-4463-89ec-95ae5c25e040

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 17, Nonsense Mutation 7, Splice Region 2, Intron 2, Frame Shift Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLD | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs886040872, CM001113, COSV61094720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.3470G>A p.R1157Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60786347; called by muse, mutect2, varscan2
- AGTPBP1 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1432996202, COSV61275761; called by muse, mutect2, varscan2
- AL031777.2 | c.104T>A p.L35H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61912527; called by muse, mutect2, varscan2
- ASH1L | c.7905+8G>A | Splice Region (SNP) | VAF 9/68 reads (13%) | catalogued as rs1387242075; called by muse, mutect2, varscan2
- CLCN7 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140032494; called by muse, mutect2, varscan2
- COL4A2 | c.5086G>A p.G1696S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs202178258; called by muse, mutect2, varscan2
- DNAH17 | c.3565G>A p.V1189M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs780662327; called by mutect2, varscan2
- GRIA2 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1268167873, COSV52403249; called by muse, mutect2, varscan2
- H4C12 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.662); catalogued as rs772156373, COSV62743962; called by muse, varscan2
- IDH3B | c.1158G>C p.*386Yext*29 | Nonstop Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV61388932; called by muse, mutect2, varscan2
- NEUROG3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV99653486; called by muse, mutect2, varscan2
- OPCML | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV59406450; called by muse, mutect2, varscan2
- PCDHB2 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1554271517; called by muse, mutect2, varscan2
- RASSF1 | c.370G>A p.D124N (on ENST00000357043 / NM_170714.2; = p.D120N on NM_007182.5) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); catalogued as rs1466210354; called by muse, mutect2, varscan2
- RNF10 | c.2357C>G p.S786C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV58048107; called by muse, mutect2, varscan2
- TBCE | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as COSV100783146; called by muse, mutect2, varscan2
- CHEK2 | c.1561G>T p.E521* (on ENST00000382580 / NM_001005735.2; = p.E478* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- COL5A2 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CRYBG1 | c.5605G>A p.E1869K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CWC15 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- DLG3 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EMP3 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EPB41L5 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- FPGT-TNNI3K | c.123C>T p.G41= | Splice Region (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- GPANK1 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- HECTD4 | c.1673del p.L558Cfs*4 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- IGLV1-36 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- INTS7 | c.1906T>G p.C636G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KATNAL2 | c.956C>T p.S319F (on ENST00000356157 / NM_001353899.1; = p.S247F on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLF3 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT19 | c.818del p.S273Tfs*6 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel*
- MARF1 | c.3416C>G p.S1139* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- MTMR7 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- NGF | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLCH1 | c.3369G>T p.L1123F (on ENST00000340059 / NM_001130960.2; = p.L1115F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PVR | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- RTTN | c.4744C>T p.Q1582* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- TAP1 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- UBA5 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- UEVLD | c.1257T>A p.Y419* (on ENST00000396197 / NM_001040697.4; = p.M378K on NM_018314.6) | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- USP9X | c.6631G>A p.D2211N | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ADGRA1 | c.1311C>T p.A437= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV66925521; called by muse, mutect2, varscan2
- ADGRA3 | c.423A>C p.I141= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- CYP2E1 | c.192C>T p.F64= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- GAS2L1 | c.588C>T p.R196= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1446804415; called by muse, mutect2
- LGMN | c.645G>A p.S215= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs753838339, COSV58402853, COSV58404575; called by muse, mutect2, varscan2
- MYBPC1 | c.1569G>A p.K523= (on ENST00000550270 / NM_206820.2; = p.K548= on NM_002465.4) | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- MYO1F | c.828C>T p.L276= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs200593021, COSV100597056; called by muse, varscan2
- NEXMIF | c.964C>A p.R322= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as CM156012, COSV50023631; called by muse, mutect2, varscan2
- OR2M2 | c.99C>A p.G33= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- PCK2 | c.522C>T p.I174= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs894314715; called by muse, mutect2, varscan2
- PHLDB2 | c.3108A>G p.E1036= (on ENST00000393925 / NM_001134439.2; = p.E993= on NM_145753.2) | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- PLEC | c.8916C>T p.F2972= (on ENST00000322810 / NM_201380.4; = p.F2862= on NM_000445.5) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs782326556, COSV59617656, COSV59624103; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- SLC47A1 | c.357T>C p.S119= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs958241453; called by muse, mutect2, varscan2
- SOX6 | c.1569C>T p.D523= (on ENST00000528429 / NM_001145819.2; = p.D496= on NM_017508.3) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs369713124; called by muse, mutect2, varscan2
- TGFBR2 | c.1644G>A p.S548= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs781309781, COSV99848630; called by muse, mutect2, varscan2
- TMEM87B | c.1138C>T p.L380= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- ZNF600 | c.1719T>G p.R573= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV100592975; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-481-2007G>A | Intron (SNP) | VAF 19/137 reads (14%) | catalogued as rs761343908; called by muse, mutect2, varscan2
- DOT1L | c.4606+733C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs753844479; called by muse, mutect2, varscan2
